Surgical pathology report (de-identified scan), TCGA case TCGA-XM-A8RL, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-A8RL-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
Physician: [REDACTED] (Age: [REDACTED] M Date of Receipt: [REDACTED]
CC: [REDACTED] Date of Report: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
Probable thymoma.

Specimens Submitted:
1: SP: Mediastinal mass (fs)
2: SP: Thymus
3: SP: AP window tissue

DIAGNOSIS:

- 1) MEDIASTINUM, EXCISION:
- THYMOMA, TYPE B1, 9.0 CM.
- THE TUMOR MICROSCOPICALLY INVADES THE CAPSULE AND IS PRESENT IN THE PERITHYMIC ADIPOSE TISSUE.
- THE SURGICAL RESECTION MARGIN IS FREE OF TUMOR.
- BENIGN THYMIC TISSUE IS ALSO PRESENT (SEE NOTE).

NOTE: THE TUMOR CELLS ARE POSITIVE FOR AE1:AE3 AND THE THYMIC LYMPHOCYTES ARE POSITIVE FOR CD1A, CD99, AND CD3.

- 2) THYMUS, EXCISION:
- BENIGN THYMIC TISSUE.
- NO TUMOR SEEN.
- 3) AP WINDOW, BIOPSY:
- BENIGN THYMIC TISSUE.
- NO TUMOR SEEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

** Continued on next page **

ICD O-3
Thymoma, Type B1, malignant
Site C40F 8583/3
Anterior mediastinum
path (38.1)
Mediastinum NOS
088.3
7-6/12/14

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service:

Date of Report:

Page 2 of 3

1). The specimen is received fresh for frozen section consultation, labeled "mediastinal mass" and consists of a 144 g, 9.0 x 8.0 x 3.5 cm encapsulated, soft, tan-pink tumor with an attached 7.0 x 3.0 x 0.4 cm portion of normal-appearing thymus tissue. One surface of the tumor is covered by smooth glistening serosa. The opposite surface is slightly roughened surgical margin. The specimen is inked black. Sectioning reveals a lobulated tan-pink, soft, fleshy, semi-liquid cut surface with focal hemorrhage. There is no extension to the surrounding adipose tissue. Representative sections are sent for frozen section. Gross photo and TPS are taken.

Summary of sections:

T tumor with capsule

M thymus margin parallel

THY normal-appearing thymus

FSC frozen section control

2). The specimen is received in formalin, labeled "thymus" and consists of one piece of yellow-tan tissue measuring 9.5 x 7.0 x 2.4 cm and weighs 47 g. The exterior surface is inked black. Sectioning through specimen reveals a homogenous tan-yellow mass. The majority of the specimen is composed of yellow fibroadipose tissue. Representative sections are submitted.

Summary of sections:

m-mass

a-adipose tissue

3). The specimen is received in formalin, labeled "AP window tissue" and consists of multiple pieces of lymphoid tissue ranging from 0.3 x 0.3 to 1.7 x 1.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph node

Summary of Sections:

Part 1: SF: Mediastinal mass (fs)

Block	Sect.	Site	PCs
1		fsc	0
1		m	0
10		t	0
1		thy	0

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:
MRN:
Account #:

Accession #:
Physician:
Service:
Date of Report:

Page 3 of 3

Part 2: SP: Thymus

Block	Sect.	Site	PCs
4	a		4
7	m		7

Part 3: SP: AP window tissue

Block	Sect.	Site	PCs
1	bln		1
1	ln		1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: THYMOMA.
PERMANENT DIAGNOSIS: SAME

** End of Report **

Source: NCI Genomic Data Commons file d50c3b86-92f4-456d-986c-f2b059694e9e (TCGA-XM-A8RL.263F95C9-99C7-48CF-8DD1-84D154ABAB7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).